Surgical pathology report (de-identified scan), TCGA case TCGA-F7-A624, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-A624-01A (Primary Tumor).

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: HEAD & NECK CHECKLIST

Specimen type: (ex: Hysterectomy)

Tumor site: Buccal mucosa

Tumor size (in cm): 3.2x2.0x1.5

Histologic type: squamous cell carcinoma (ex: Squamous cell carcinoma)

Histologic grade:

Tumor extent:

Lymph nodes:

Lymphatic invasion:

Venous invasion:

Margins:

Evidence of neo-adjuvant treatment:

If yes, type of treatment seen:

Severity of treatment effect:

Comments: vimentin+, HMWcytokeratins+, CK7+; S100-, HMB45-, chromogranin-, CD56-; ki 67+ in 90%

ICD-O-3
Carcinoma, squamous cell NOS
8676/3
Site: Buccal mucosa
CO6.0
JW 4/12/13

Source: NCI Genomic Data Commons file 0fb52561-4577-481a-9876-b2fa470875f5 (TCGA-F7-A624.C43D47D4-96B7-4254-B6BE-5BC2B527CE0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).